Gene-level copy-number profile of tumor specimen ALCH-B73V-TTP1-A from ALCHEMIST case ALCH-B73V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,298 days).
Specimen ALCH-B73V-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7624d2b7-437b-4972-b876-0a7abaf8f952.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B73V-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/723371db-5dd6-4733-b8d5-e321d10c39ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 687; copy number 2: 57,470; copy number 3: 150; copy number 4: 10; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,143,166–9,146,106, 1 gene: AC093904.1.
- chr2:26,173,088–26,189,663, 1 gene: GAREM2.
- chr2:43,812,472–43,838,865, 1 gene: ABCG5.
- chr2:62,463,127–62,464,070, 1 gene: AC093159.1.
- chr15:25,193,321–25,225,284, 18 genes (within-gene range 0–2): SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr16:1,938,229–1,943,293, 1 gene: MSRB1.
- chr16:35,547,917–35,912,516, 31 genes: AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:16,438,767–16,478,678, 5 genes (within-gene range 0–2): SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65.
- chr19:24,033,401–27,794,005, 10 genes (within-gene range 0–2): AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr21:12,999,676–13,120,807, 5 genes: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 11 (within-gene range 1–11): TTC34, AC242022.2, AC242022.1.

Autosomal genes at a single copy (total copy number 1): 686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
